Somatic mutation profile of tumor specimen 0DJE3D from CCDI case PBBWWF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 7.8 years (2,841 days).
Specimen 0DJE3D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1050df38-4712-4505-b875-f62bad64126d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJE3J (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be21c329-fd67-4845-96a0-888db57082ec

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Frame Shift Del 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYLD | c.2272C>G p.R758G | Missense Mutation (SNP) | VAF 132/461 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as CM001116, COSV100282806, COSV61092791; called by muse, mutect2, varscan2
- ICE1 | c.6230C>T p.P2077L | Missense Mutation (SNP) | VAF 206/532 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1358470317, COSV99665272; called by muse, mutect2, varscan2
- NCF4 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 250/358 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as rs572795915, COSV99957180; called by muse, mutect2, varscan2
- NOS1AP | c.803G>A p.R268K | Missense Mutation (SNP) | VAF 82/1311 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1359612508; called by muse, mutect2
- ERO1B | c.1369_1372delinsAG p.Q457Rfs*3 | Frame Shift Del (DEL) | VAF 206/632 reads (33%) | called by pindel, varscan2*
- ZSCAN26 | c.398T>G p.L133R | Missense Mutation (SNP) | VAF 278/695 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPHA7 | c.1071T>C p.N357= | Silent (SNP) | VAF 396/996 reads (40%) | catalogued as rs1268869019; called by muse, mutect2, varscan2
- RSPH6A | c.741G>A p.T247= | Silent (SNP) | VAF 245/596 reads (41%) | catalogued as rs771884389; called by muse, mutect2, varscan2
- CDNF | c.-9T>A | 5'UTR (SNP) | VAF 11/352 reads (3%) | called by muse, mutect2
- SYCE1 | c.319+68G>C | Intron (SNP) | VAF 200/514 reads (39%) | called by muse, mutect2, varscan2
